Somatic mutation profile of tumor specimen TARGET-20-PASHYZ-04A (aliquot TARGET-20-PASHYZ-04A-03D) from TARGET case TARGET-20-PASHYZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,695 days).
Specimen TARGET-20-PASHYZ-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b512328-bdd4-4e89-8811-ac2c028c6a1d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASHYZ-14A (Bone Marrow Normal), aliquot TARGET-20-PASHYZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b7d6a2e-70b2-47fa-892d-142e255ab1ea

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.12545G>T p.G4182V | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV71674346; called by muse, mutect2, varscan2
- KIT | c.2460_2465delinsGACTTT p.D820_N822delinsETF | Missense Mutation (ONP) | VAF 35/212 reads (17%) | called by mutect2*, pindel
